Somatic mutation profile of tumor specimen TCGA-DK-A6B0-01A (aliquot TCGA-DK-A6B0-01A-11D-A31L-08) from TCGA case TCGA-DK-A6B0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 61.4 years (22,439 days).
Specimen TCGA-DK-A6B0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d05f41-6a29-4320-9537-abe2114e3a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6B0-10A (Blood Derived Normal), aliquot TCGA-DK-A6B0-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/915ec260-f344-49cd-8d0f-6167a47019a7

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 268/292 reads (92%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AKT3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV55615749, COSV55620508; called by muse, mutect2, varscan2
- CHRNA4 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs978124935, COSV64720082; called by muse, mutect2, varscan2
- CNNM1 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV63202190; called by muse, mutect2, varscan2
- COL5A3 | c.2083G>A p.G695R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778826937, COSV53413118; called by muse, mutect2, varscan2
- COL6A3 | c.8770G>A p.A2924T | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55094637; called by muse, mutect2, varscan2
- CREBBP | c.6580_6592del p.R2194Cfs*104 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV52128328; called by mutect2, pindel
- DENND4C | c.5125A>G p.T1709A (on ENST00000434457 / NM_001330640.2; = p.T1660A on NM_017925.7) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63009127; called by muse, mutect2, varscan2
- DLG5 | c.1825A>T p.I609F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64948526; called by muse, mutect2, varscan2
- DROSHA | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1415409157, COSV60778112; called by muse, mutect2, varscan2
- GNG11 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 13/19 reads (68%) | catalogued as COSV99949302; called by muse, mutect2, varscan2
- HELLS | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53298578; called by muse, mutect2, varscan2
- IL16 | c.3224T>G p.L1075R (on ENST00000302987 / NM_172217.5; = p.L374R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV57264812; called by muse, mutect2, varscan2
- ITGAV | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53714381; called by muse, mutect2
- KDM6A | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65042070; called by muse, mutect2, varscan2
- KLF5 | c.411_412insCAT p.N137_V138insH | In Frame Ins (INS) | VAF 52/139 reads (37%) | catalogued as COSV100890477; called by mutect2, pindel, varscan2
- LAPTM4A | c.269T>G p.M90R | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV51532723; called by muse, mutect2, varscan2
- MASP2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV68896906; called by muse, mutect2, varscan2
- MLLT3 | c.1291A>G p.M431V | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV63498545; called by muse, mutect2, varscan2
- MYH14 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs371046797; called by muse, mutect2, varscan2
- SLC19A1 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755188060, COSV60755517; called by muse, varscan2
- USP34 | c.1880A>G p.D627G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as COSV68402673; called by muse, mutect2, varscan2
- CNOT1 | c.375dup p.E126Rfs*17 | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- STAG2 | c.984_987del p.Y328* | Frame Shift Del (DEL) | VAF 65/69 reads (94%) | called by mutect2, pindel*, varscan2*
- MUC16 | c.14928C>T p.T4976= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV67475086; called by muse, mutect2, varscan2
- ZFP42 | c.162G>A p.V54= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV58817982; called by muse, mutect2, varscan2
- ZNF536 | c.2094C>T p.S698= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1049655705, COSV62826684; called by muse, mutect2, varscan2
